Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5730, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5730-01A (Primary Tumor).

*** Diagnosis(-es): ***

1. and 4.: Gastrectomy specimen including a moderately differentiated adenocarcinoma or gastric carcinoma of the intestinal type [REDACTED] extending microscopically as far as the oral resection margin with the main mass located subcardially, involving infiltration of the perimuscular fatty tissue, several regional lymph node metastases and a hepatic metastasis (pT2b pN1 6/15 pM1 [REDACTED])
- 2.: Splenectomy specimen with fresh capsule and parenchymal defect.
- 3.: Tumor-free gallbladder without appreciable florid or chronic inflammatory changes.
- 5.: Wedge excision specimen of the liver (section 8) including a partially sclerosed subcapsular hemangioma.

Source: NCI Genomic Data Commons file 2ce9df92-0e76-4eac-9731-4af893f23735 (TCGA-CG-5730.C6AC1E92-A6E3-429B-90A1-94F4FC6C955F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).